Somatic mutation profile of tumor specimen TARGET-10-PARLBP-09A (aliquot TARGET-10-PARLBP-09A-01D) from TARGET case TARGET-10-PARLBP, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.0 years (3,662 days).
Specimen TARGET-10-PARLBP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c4bbfdd0-2c8a-424f-bb1b-5f74e9bff4ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARLBP-14A (Bone Marrow Normal), aliquot TARGET-10-PARLBP-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5162e05-8208-418a-b3ad-fcf7ea47ffd7

The open-access MAF lists 13 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 4, Frame Shift Del 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.68T>G p.L23R | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs730880472, COSV55534139; ClinVar: likely pathogenic; called by muse, varscan2
- NTRK2 | c.1745G>A p.R582H (on ENST00000323115 / NM_001369534.1; = p.R598H on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as rs147652140; called by muse, mutect2, varscan2
- STAB1 | c.6949G>A p.G2317R | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs923593643; called by muse, mutect2, varscan2
- TMEM130 | c.1087C>T p.R363W | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as rs142570247, COSV59561389; called by muse, mutect2, varscan2
- ZNF398 | c.1675C>T p.R559C (on ENST00000475153 / NM_170686.3; = p.R388C on NM_020781.4) | Missense Mutation (SNP) | VAF 81/159 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs140277862; called by muse, mutect2, varscan2
- MYO15B | c.6254A>T p.E2085V | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- PCDHAC1 | c.196_197del p.F66Rfs*53 | Frame Shift Del (DEL) | VAF 59/124 reads (48%) | called by mutect2, pindel*, varscan2*
- CDC14B | c.1260C>T p.D420= | Silent (SNP) | VAF 14/121 reads (12%) | catalogued as rs759467017; called by muse, mutect2, varscan2
- FOXN1 | c.1887G>A p.T629= | Silent (SNP) | VAF 47/98 reads (48%) | catalogued as rs538932844, COSV56882410, COSV56884134; called by muse, mutect2, varscan2
- KCNH7 | c.969C>T p.L323= | Silent (SNP) | VAF 49/114 reads (43%) | catalogued as rs751184207; called by muse, mutect2, varscan2
- MEF2D | c.501C>T p.S167= | Silent (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2, varscan2
- RHBDL3 | c.112-70A>T | Intron (SNP) | VAF 6/72 reads (8%) | catalogued as COSV99283666; called by muse, mutect2
- ZSWIM4 | chr19:13836588 G>A | 3'Flank (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
